Gene-level copy-number profile of tumor specimen TCGA-RC-A7SK-01A from TCGA case TCGA-RC-A7SK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.7 years (21,814 days).
Specimen TCGA-RC-A7SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.db4b8591-9c42-4e3b-9e6f-b67fd043e1e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RC-A7SK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40b461cc-1935-4f45-b246-efae3b7c0e9f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,414; copy number 2: 6,985; copy number 3: 15,865; copy number 4: 24,610; copy number 5: 7,748; copy number 6: 983; copy number 7: 490; copy number 8: 227; copy number 9: 53; copy number 10: 200; copy number 11: 2; copy number 13: 51; copy number 14: 19; copy number 15: 35; copy number 16: 38; copy number 17: 24; copy number 18: 20; copy number 19: 6; copy number 21: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RC-A7SK-01A-11D-A34Y-01): tumor purity 0.68, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 484 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:206,443,532–207,769,906, 38 genes, copy number 16 (within-gene range 8–16): ADAM23, AC010731.1, AC010731.2, FAM237A, DYTN, VPS26CP1, Y_RNA, MDH1B, FASTKD2, MIR3130-2, MIR3130-1, AC008269.1, AC008269.2, CPO, KLF7, MIR2355, KLF7-IT1, MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5.
- chr6:76,446,988–78,813,303, 12 genes, copy number 10: RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1.
- chr6:79,201,245–80,346,270, 29 genes, copy number 9 (within-gene range 3–9): HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2, LINC01621, AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK, AL591135.2, AL591135.1, AK4P5, BCKDHB.
- chr8:76,162,119–76,308,315, 2 genes, copy number 11: AC011029.1, RNU2-54P.
- chr8:89,823,548–93,700,433, 52 genes, copy number 10–14 (within-gene range 7–14): COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274.
- chr8:94,201,913–98,294,393, 79 genes, copy number 10 (broad region; genes not listed).
- chr8:98,391,401–98,463,050, 5 genes, copy number 10: AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P.
- chr8:106,359,476–121,641,440, 130 genes, copy number 9–18 (broad region; genes not listed).
- chr8:122,414,332–129,683,770, 131 genes, copy number 10–21 (broad region; genes not listed).
- chr8:135,455,865–135,742,495, 4 genes, copy number 9: AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:135,977,329–136,295,232, 2 genes, copy number 9: AC103955.1, AC023781.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
